Surgical pathology report (de-identified scan), TCGA case TCGA-IB-AAUP, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-AAUP-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
		Location	

Copied To

Report Patient Name:
Demographics (for verification purposes)
Sex: M

ICD-0.3
Adenocarcinoma, duct 8500/3
Date: Pancreas head C25.0
JW 5/20/14

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist
Specimen Description
A. Gallbladder at
B. Common bile duct lymph node
C. Level 8 lymph node at
D. Whipple's specimen at
Clinical Information
Pancreatic cancer.

Diagnosis

A. Gallbladder:

- gallbladder mucosa with nonspecific chronic and acute inflammation.
- Negative for malignancy.
- No gallstone identified.
- Cyst duct patent.

B. Common Bile Duct Lymph Node:

- Reactive lymph node, negative for malignancy.

C. Level 8 Lymph Node:

- Reactive lymph node, negative for malignancy.

D. Pancreas and Duodenum, Whipple Procedure:

- Invasive moderately differentiated ductal adenocarcinoma of pancreas.
- Carcinoma invaded tissue around common bile duct, perianillary duodenal mucosa (including mucosa layer) and peripancreatic soft tissue.
- Duodenal-pancreas fistula formation due to carcinoma infiltration and abscess.
- Positive for lymph-vascular invasion.
- Positive for perineural invasion.
- Uncinate margin focally involved by carcinoma.
- PanIN3 seen.
- Seven of nineteen (7/19) peripancreatic lymph nodes positive for metastatic carcinoma.
- Peripancreatic soft tissue resection margin less than 0.1 cm from infiltrating carcinoma.
- Distal resection margin of pancreas free of tumor, at least 0.6 cm away.
- Proximal resection margin of stomach and distal resection margin of duodenum free of tumor.
- See Synoptic Report.

[page 2 of 3]
Reported by:
Electronically signed by:
Verified:

Synoptic Report

SPECIMEN:

Head of pancreas

Duodenum

Common bile duct

Gallbladder

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE:

Greatest dimension: 2.7 cm

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades ampulla of Vater or sphincter of Oddi

Tumor invades duodenal wall

Tumor invades peripancreatic soft tissues

Tumor invades retroperitoneal soft tissue

MARGINS:

Margin(s) involved by invasive carcinoma

Uncinate process (retroperitoneal) margin (nonperitonealized surface of the uncinate process)

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

Not known

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

ADDITIONAL PATHOLOGIC FINDINGS:

Pancreatic intraepithelial neoplasia (highest grade: PanIN 3)

Gross Description

Received are specimen containers A to D. All sections and specimen containers are labelled with the patient's name, cassettes and identifiers are labelled with the Surgical Number

A. Specimen is received fresh. One container is designated "Gallbladder". The specimen consists of a cholecystectomy specimen. The gallbladder is intact and measures 8.4 x 4.0 x 3.0 cm. The serosal surface appears unremarkable. The cystic duct is patent. Upon opening, no gallstones are seen. The cystic mucosa appears unremarkable. Representative sections are submitted in one cassette.

B. The specimen is received fresh and is subsequently placed into formalin. The container is designated as "common bile duct lymph node". The specimen consists of one lymph node, 1.7 cm. The lymph node is bisected and submitted in cassettes B1 and B2.

C. The specimen is received fresh and is subsequently placed into formalin. The container is designated "C. Level 8 lymph node". The specimen consists of a lymph node, 2.8 cm in largest dimension. The lymph node is bisected and submitted in C1 and C2.

D. The specimen is received fresh and is subsequently placed into formalin. The container is designated as "Whipple's specimen". The specimen consists of a segment of duodenum and portion of distal stomach, 26.0 cm in length and 8.5 cm in circumference. The distal duodenum, up to 8.0 cm long, appears hemorrhagic. Attached with the duodenum is a portion of pancreas, 6.5 x 5.0 x 2.0 cm, with unremarkable outer surface and resection margin. No tumor nodule is seen in the peripancreatic fat. The distal portion of the common bile duct is identified, 4.2 cm in length and 1.8 cm in circumference. A metal stent is seen within the common bile duct. The common bile duct appears hemorrhagic and rough. The ampullary region mucosa appears slightly elevated. At 2.5 cm away from the ampulla, there is an area of mucosal depression seemingly adherent with the underlying lesion. At 1.0 cm away from the depressed mucosa, is a duodenal diverticula. Otherwise, the duodenal mucosa appears unremarkable. At 2.0 cm proximal to the ampullary opening, there is suspicious opening of pancreatic duct which is contiguous with the common bile duct. Serial cross-sections through the pancreas reveal an ill-defined mass

[page 3 of 3]
lesion, 2.7 cm in maximum dimension. The pancreatic lesion appears to be 0.1 cm away from the distal resection and 0.1 cm from the uncinata margin. The distal pancreatic margin is inked blue and the uncinata margin is inked orange. The pancreatic lesion appears to invade around the common bile duct and focally invades into the submucosa of the duodenum.

Representative sections are submitted in cassettes labeled as follows:

- D1 - shaved margin of common bile duct.
- D2 - duodenal diverticula
- D3 through D5 - area of depressed duodenal mucosa with underlying lesion
- D6 - cross-section of the tract suspicious for additional pancreatic duct opening.
- D7 and D8 - cross-section through ampulla and pancreas.
- D9 and D10 - single cross-section through ampullary opening, common bile duct and pancreas.
- D11 and D12 - single cross-section through ampullary opening, common bile duct and pancreas
- D13 through D15 - cross-section of common bile duct and surrounding pancreas.
- D16 through D18 - single longitudinal cross-section through common bile duct and ampulla.
- D19 and D20 - single cross-section of distal common bile duct and pancreas.
- D21 through D23 - distal resection margin of pancreas.
- D24 and D25 - uncinata margin.
- D26 - tumor with overlying duodenum.
- D27 and D28 - cross-sections of distal common bile duct with tumor.
- D31 - single lymph node close to common bile duct.
- D32 - one bisected lymph node.
- D33 - one peripancreatic lymph node.
- D34 - one additional section of pancreatic mass.
- D35 - one bisected peripancreatic lymph node
- D36 - perpendicular proximal resection margin.
- D37 - shaved distal resection margin.
- D38 - three peripancreatic lymph nodes, with one bisected.

Accession Number
Encounter Number
Patient Location

hw 11/7/14

B.T.R.

Source: NCI Genomic Data Commons file 580abed0-c896-4d08-81d1-63b1d6e394cf (TCGA-IB-AAUP.DAFC0F31-63B8-4041-8D7C-F21D71A8A305.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).